CCDI case PBBWBV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/155582d4-2da6-47c0-a833-367490d609eb

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,109 days).

Biospecimens (3 samples)
- Sample 0DIQZR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR0D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR3Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
